Gene-level copy-number profile of tumor specimen TCGA-V1-A8MM-01A from TCGA case TCGA-V1-A8MM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.bca3d5af-7305-45eb-aee0-b9730f6c2cbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A8MM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 844 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5d0807f-8ef3-4f79-8e77-d9e8c7c5371d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 6,376; copy number 2: 51,707; copy number 3: 631; copy number 4: 521; copy number 5: 322; copy number 6: 171.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A8MM-01A-11D-A376-01): tumor purity 0.78, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:134,119,983–135,531,218, 16 genes (within-gene range 0–1): MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3.
- chr2:138,412,066–142,137,830, 33 genes: RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3, AC078882.1.
- chr5:88,189,633–88,269,476, 1 gene: TMEM161B.
- chr5:88,274,258–88,274,376, 1 gene: RNA5SP187.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 493 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:34,784,028–36,321,404, 16 genes, copy number 5 (within-gene range 1–5): LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:47,667,771–48,064,708, 8 genes, copy number 5: RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2.
- chr8:66,667,596–66,860,472, 1 gene, copy number 6 (within-gene range 4–6): C8orf44-SGK3.
- chr8:66,712,734–72,938,349, 87 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:73,215,929–86,743,675, 216 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:118,620,498–121,994,185, 40 genes, copy number 5 (within-gene range 4–5): SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855.
- chr8:126,474,189–135,656,722, 125 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
